Surgical pathology report (de-identified scan), TCGA case TCGA-FG-7636, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-7636-01A (Primary Tumor).

[page 1 of 3]
Date of Collection:

Copies to:

Clinical History: Left frontal temporal craniotomy for tumor resection with image guidance and awake mapping
Pre-Operative Diagnoses: None Given
Post-Operative Diagnosis: Same
Specimen(s) Submitted: A. Left tumor- F/S; B. Left tumor- S/P
CPT Code(s): 88307 X 2; 88333 X 1; 88342 X 1; 88360 X 1

FINAL DIAGNOSIS:

A. Left frontotemporal mass: Anaplastic astrocytoma (WHO grade III). See note.

Copies to: CEROX

B. Left frontotemporal mass: Anaplastic astrocytoma (WHO grade III). See note.

Clinical History:

Note: This astrocytoma diffusely infiltrates white and gray matter. Perineuronal satellitosis is seen. The cellularity is moderate to high, with areas of marked nuclear pleomorphism and scattered mitoses. No vascular endothelial proliferation or areas of necrosis are present. Immunostain for MIB-1 (slide B1) shows an increased nuclear labeling rate of up to 11% (rates of greater than 3% are considered likely to represent anaplastic change by [redacted] and its Coverings, 4th ed.). Many nuclei are immunopositive for p53, supporting the diagnosis. The tumor corresponds to a WHO grade III. Studies for MGMT, IDH1 and 1p19q are in progress.

BRAIN: Resection

MACROSCOPIC

Specimen Type

☒ Resection

Technical Performing Location: 1

questions regarding this case:

For

[page 2 of 3]
NEUROPATHOLOGY REPORT

Pathology #:

Specimen Size

Greatest dimension: 6 x 3.5 x 1 cm aggregate

Tumor Site (check all that apply)

☒ Cerebrum (specify lobe[s], if known): frontal

Tumor Size

☒ Cannot be determined (see Comment)

MICROSCOPIC

Histologic Type

☒ Anaplastic astrocytoma

Histologic Grade

☒ WHO Grade III

Margins

☒ Cannot be assessed

*Additional Studies (check all that apply)

* ☒ Molecular testing (specify): See above

Frozen Section Diagnosis:

- A. Left brain tumor ()
- Infiltrating astrocytoma, grade 2-3.

Gross Description:

- A. Received fresh for frozen section, labeled "left tumor," is a 1.9 x 1.0 x 0.4 cm aggregate of tan-white soft tissue that is entirely submitted in blocks A1 and A2.
- B. Received fresh, labeled with the patient's name and demographics and "left tumor," is a 12 g, 6 x 3.5 x 1 cm aggregate of multiple pieces of gray-white irregular soft tissue. The specimen is step-sectioned and representative sections (about 40% of the total specimen) are submitted in cassettes B1-B5.

Microscopic Description:

[page 3 of 3]
NEUROPATHOLOGY REPORT

Pathology #:

6 H&E; immunostains for p53, MIB1 (semiquant)

I have reviewed all diagnostic slides and have edited the gross and/or microscopic portion of this report as part of my pathologic assessment and final diagnosis.

The pathologist signing this report is located at

Source: NCI Genomic Data Commons file 33327fbe-9c9d-4219-8ed4-c349be7d3b8d (TCGA-FG-7636.F257E22A-45D4-4C1D-B18E-8DCD42AC04B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).